CPTAC case SC-0216 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fd24dcaf-f627-47da-9ba7-90fbf3f24327

Demographics
Sex at birth: male; Vital status: Dead; Days to death: 1,613 days (4.4 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of lower limb and hip; Age at diagnosis: 71.0 years (25,933 days); AJCC staging edition: 8th; AJCC pathologic T: T4b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIC; Last known disease status: With tumor; Days to last known disease status: 1,613 days (4.4 years); Progression or recurrence: yes; Days to recurrence: 639 days (1.7 years); Clark level: V.
   Pathology details: Breslow thickness: 6.2.

Biospecimens (1 sample)
- Sample S-1706-005665: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Frozen; Initial weight: 180 mg; Method of sample procurement: Tumor Resection.
